Surgical pathology report (de-identified scan), TCGA case TCGA-14-2555, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-2555-01B (Primary Tumor).

[page 1 of 5]
AP Report

* Final Report *

TCGA-14-2555

Document Type: AP Report
Document Date:
Document Status: Modified
Document Title: AP REPORT
Encounter info:

* Final Report *

AP REPORT

Patient:

Accession Number:

Date Collected:

Date Received:

Financial Number:

Room/Bed:

PT:

Admitting Physician:

Ordering Physician:

SUPPLEMENTAL REPORT

SUPPLEMENTAL DIAGNOSIS:

The diagnoses are unchanged.

COMMENT:

MGMT GENE AMPLIFICATION

DNA was isolated from a paraffin embedded block of the brain tumor biopsy
DNA methylation patterns in the CpG island of the MGMT gene
(bisulfite) modification of unmethylated, but not methylated, cytosines to
uracil and subsequent PCR using primers specific for either methylated or the
modified unmethylated DNA () The
PCR products were analyzed in duplicate parallel runs by capillary gel
electrophoresis. The sensitivity of the assay based on DNA dilution studies
is at least 1:1000.

RESULT:

The analyzed region of the MGMT promoter is UNMETHYLATED

Printed by:
Printed on:

Page 1 of 6
(Continued)

[page 2 of 5]
AP Report

* Final Report *

INTERPRETATION:

MGMT (O6 methylguanine DNA methyltransferase) is a DNA repair gene. Methylation of the promotor leads to gene silencing and loss of MGMT expression. a recent study that tested the methylation status of the same region of the MGMT promoter in glioblastomas found that MGMT promoter methylation was an independent favorable prognostic factor and was associated with a survival benefit in patients treated with temozolamide and radiotherapy.

This test was not requested, performed or reported at Hospital Department of Pathology.

The test was requested by . The test was performed and results reported by , Department of Pathology,

Results are included with this Surgical Pathology report so that all available information on this tumor may be accessed at one site.

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. RIGHT TEMPORAL BRAIN LESION, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA, WHO GRADE IV.
- SEE COMMENT.
2. RIGHT TEMPORAL BRAIN LESION, RESECTION:
- GLIOBLASTOMA, WHO GRADE IV.
- SEE COMMENT.
3. DURA, RESECTION:
- SECTION OF DURA WITH UNDERLYING GLIOBLASTOMA, WHO GRADE IV.
- SEE COMMENT.

Page

Printed by:
Printed on:

Page 2 of 6
(Continued)

[page 3 of 5]
AP Report

* Final Report *

Patient: [REDACTED]
Patient Number: [REDACTED]

Accession Number: [REDACTED]

SURGICAL PATHOLOGY REPORT

COMMENT:

This malignant neoplasm stains positively for GFAP and a stain for CD34 highlights the highly proliferative blood vessels of this neoplasm. Tumor necrosis is identified, fulfilling the criteria for glioblastoma, WHO grade IV. Immunohistochemistry for neurofilament shows neoplastic cells invading neurofilament positive axons. FISH analysis for EGFR gene status will be performed and a separate report will be issued. Tissue will be sent for MGMT analysis and a separate report will be issued.

SPECIMEN:

1. Right temporal brain lesion.
2. Right temporal brain lesion.
3. Dura.

CLINICAL HISTORY/OPERATIVE FINDINGS:

None provided.

GROSS DESCRIPTION:

Specimen #1 is received fresh for intraoperative consultation and is labeled with the patient's name and medical record number and as "right temporal brain lesion." The specimen consists of red and white brain tissue that is soft in consistency which measures 2.5 x 1.5 x 0.4 cm. A representative section is taken for frozen section diagnosis and the cryoblock is transferred to cassette "FS1A." The rest of the specimen is submitted in cassette "1B." Dictated by Dr. [REDACTED]

Specimen #2 is received in formalin and is labeled with the patient's name and medical record number and as "right frontal brain lesion." The specimen consists of multiple fragments of brown and white brain tissue measuring 3.0 x 2.6 x 0.6 cm in aggregate. Representative sections are submitted in cassettes "2A" and "2B." Dictated by [REDACTED]

Printed by:
Printed on:

Page 3 of 6
(Continued)

[page 4 of 5]
AP Report

* Final Report *

Specimen #3 is received in formalin and is labeled with the patient's name and medical record number and as "dura." The specimen consists of one piece of fibrous soft tissue, measuring 4.5 x 2.1 x 0.3 cm. Representative sections are submitted in cassette "3A." Dictated by

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT TEMPORAL BRAIN LESION, BIOPSY (FROZEN SECTION, TOUCH PREPARATION): GLIOBLASTOMA.

Frozen Section results were communicated to the surgical team and were repeated back by

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

SPECIAL STAINS:

GFAP	DONE
CD34	DONE
NF	DONE
FISH	DONE
FISH	DONE

Page 2 (Continued...)

Patient:
Patient Number:

Accession Number:

FLUORESCENCE IN SITU HYBRIDIZATION

Printed by:
Printed on:

Page 4 of 6
(Continued)

[page 5 of 5]
AP Report

* Final Report *

SPECIMEN:

Brain, right temporal brain lesion.

CLINICAL HISTORY/REFERRING DIAGNOSIS:

Glioblastoma, WHO grade IV.

GROSS DESCRIPTION:

Paraffin block, labeled 2A.

TEST PERFORMED/PROBES USED:

EGFR gene locus specific probe(7p12)

Chromosome 7 alpha satellite DNA specific probe(7p11.1-7q11.1)

RESULTS:

POSITIVE for EGFR gene amplification
nuc ish amp(EGFR)[193/200]

INTERPRETATION:

Flourescence in situ hybridization was performed using the above listed DNA probes(Abbott Molecular, Inc.).The probes were simultaneously hybridized to a section of the formalin-fixed paraffin-embedded tissue submitted for evaluation.

Of 200 interphase nuclei analyzed, 96% of cells were POSITIVE for EGFR gene amplification. Positive and negative controls were appropriate. Correlation with clinical and other laboratory parameters is suggested.

COMMENT:

The results of this test should not be used alone as the sole basis for diagnosis and/or treatment. These results may, however, prove useful when used in conjunction with other diagnostic procedures and clinical evaluations. Use of these results, in this manner, can be considered to fall within the scope of practice of medicine. This test was developed and its performance characteristics determined by the [REDACTED] It has been cleared or approved by the U.S. Food and Drug Administration.

Printed by:
Printed on:

Page 5 of 6
(Continued)

Source: NCI Genomic Data Commons file 1c66805e-6702-402e-8738-d6205e9a3f14 (TCGA-14-2555.0589C710-33E8-4C4B-98EA-41B47635085D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).